Somatic mutation profile of tumor specimen TCGA-Y8-A897-01A (aliquot TCGA-Y8-A897-01A-11D-A35Z-10) from TCGA case TCGA-Y8-A897, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 68.6 years (25,047 days).
Specimen TCGA-Y8-A897-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db7ae662-304f-4fd7-b6a5-d426eb2dcc08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Y8-A897-10A (Blood Derived Normal), aliquot TCGA-Y8-A897-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3c76df8-8b17-4c90-a57b-3cbc058dd7af

The open-access MAF lists 70 somatic variants for this specimen: 57 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 12, Frame Shift Del 6, Nonsense Mutation 3, Frame Shift Ins 3, Splice Site 2, Splice Region 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB6 | c.939G>C p.K313N | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99521706; called by muse, mutect2, varscan2
- ADGRV1 | c.12569T>G p.F4190C | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV101315672; called by muse, mutect2, varscan2
- AKR1A1 | c.884A>G p.N295S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100698694; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2113C>T p.Q705* | Nonsense Mutation (SNP) | VAF 36/109 reads (33%) | catalogued as rs1359001964, COSV100376897; called by muse, mutect2, varscan2
- BAZ2A | c.5576C>T p.A1859V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs778667609, COSV99465207; called by muse, mutect2, varscan2
- CD109 | c.3490A>G p.I1164V | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.042); catalogued as rs200866355, COSV99753034; called by muse, mutect2, varscan2
- CD163 | c.2450T>C p.I817T | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV100775747; called by muse, mutect2, varscan2
- CDC5L | c.1460A>G p.K487R | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.078); catalogued as COSV101014916; called by muse, mutect2, varscan2
- CLEC18C | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 82/453 reads (18%) | catalogued as COSV100032129; called by muse, mutect2, varscan2
- CMYA5 | c.688A>C p.K230Q | Missense Mutation (SNP) | VAF 81/252 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.609); catalogued as COSV101483959; called by muse, mutect2, varscan2
- CNDP2 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866607191, COSV100159024; called by muse, mutect2, varscan2
- COL15A1 | c.2393T>C p.I798T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100897532, COSV66647846; called by muse, mutect2, varscan2
- FBF1 | c.1674C>G p.S558R (on ENST00000586717; = p.S572R on NM_001319193.1) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV100044893; called by muse, mutect2, varscan2
- FKBP8 | c.563T>C p.I188T (on ENST00000222308 / NM_001308373.2; = p.I189T on NM_012181.5) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV55892893; called by muse, mutect2, varscan2
- GPD2 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100133082; called by muse, mutect2, varscan2
- GRM5 | c.2353T>A p.W785R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550990; called by muse, mutect2, varscan2
- HECTD1 | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV101237332; called by muse, mutect2, varscan2
- HERC6 | c.2764C>A p.Q922K | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs1404391766, COSV99986428; called by muse, mutect2, varscan2
- HMCN1 | c.3772G>T p.V1258F | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99626267; called by muse, mutect2
- HS3ST4 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.986); catalogued as COSV100500589; called by muse, mutect2
- ITGA5 | c.730T>A p.S244T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.023); catalogued as COSV99516468; called by muse, mutect2, varscan2
- KIF1A | c.2556G>A p.R852= | Splice Region (SNP) | VAF 28/83 reads (34%) | catalogued as rs1326654935, COSV100240279; called by muse, mutect2, varscan2
- LAMC3 | c.188C>A p.P63H | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100735921; called by muse, mutect2, varscan2
- MAML2 | c.881G>C p.G294A | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV101594073; called by muse, mutect2, varscan2
- NUP133 | c.954A>T p.E318D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.642); catalogued as COSV99772745; called by mutect2, varscan2
- NXPH1 | c.328G>T p.V110F | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV101339632; called by muse, mutect2, varscan2
- OR51D1 | c.130C>A p.L44M | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100712356; called by muse, mutect2, varscan2
- OR52E2 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100384716; called by muse, mutect2, varscan2
- OR52E2 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV100384717; called by muse, mutect2, varscan2
- OXT | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1272801459, COSV54132308; called by muse, mutect2, varscan2
- PCNT | c.5345del p.G1782Afs*21 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | catalogued as COSV64025521; called by mutect2, varscan2
- PNPLA5 | c.42C>A p.F14L | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99336545; called by muse, mutect2
- PTEN | c.48del p.Q17Kfs*7 | Frame Shift Del (DEL) | VAF 35/70 reads (50%) | catalogued as CM110154, COSV64288363, COSV64293151, COSV64295030; called by mutect2, pindel, varscan2
- PTPRM | c.74-2A>C p.X25_splice | Splice Site (SNP) | VAF 25/77 reads (32%) | catalogued as COSV100156084; called by muse, mutect2, varscan2
- RAP1GAP2 | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99622707; called by muse, mutect2, varscan2
- RBM6 | c.2685T>G p.P895= | Splice Region (SNP) | VAF 23/68 reads (34%) | catalogued as COSV99804912; called by muse, mutect2, varscan2
- RPL10A | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs756605167, COSV100003253; called by muse, mutect2, varscan2
- SLC4A2 | c.2971G>A p.V991M | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as COSV99879633; called by muse, mutect2, varscan2
- SLC9A7 | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100091758; called by muse, mutect2, varscan2
- SUCO | c.1053T>A p.F351L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99742335; called by muse, mutect2, varscan2
- TMEM82 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV101007858; called by muse, mutect2
- TNRC6C | c.3803C>G p.A1268G | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV100049669; called by muse, mutect2, varscan2
- TRDMT1 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 103/161 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100003831; called by muse, mutect2, varscan2
- TSC2 | c.4471A>G p.K1491E | Missense Mutation (SNP) | VAF 514/972 reads (53%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.912); catalogued as COSV99237563; called by muse, mutect2, varscan2
- USH2A | c.1630A>T p.T544S | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100231784, COSV56436272; called by muse, mutect2, varscan2
- USP36 | c.2182G>A p.V728I | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs763408313, COSV61752452, COSV61753097; called by muse, mutect2, varscan2
- ZFYVE1 | c.1766A>G p.Q589R | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV100606642; called by muse, mutect2, varscan2
- ZNF318 | c.6428C>T p.S2143F | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV100546051; called by muse, mutect2, varscan2
- ZNF579 | c.1648A>C p.S550R | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV100329219; called by muse, mutect2, varscan2
- EXTL1 | c.1295del p.P432Lfs*2 | Frame Shift Del (DEL) | VAF 39/118 reads (33%) | called by mutect2, pindel, varscan2
- GAPVD1 | c.3630dup p.A1211Sfs*49 (on ENST00000394104; = p.A1220Sfs*49 on NM_015635.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 18/74 reads (24%) | called by mutect2, varscan2
- GAPVD1 | c.3635dup p.Y1213Ifs*47 (on ENST00000394104; = p.Y1222Ifs*47 on NM_015635.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 17/93 reads (18%) | called by mutect2*, pindel, varscan2*
- KIF26A | c.2298del p.D767Tfs*55 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | called by mutect2, pindel, varscan2
- MYNN | c.472dup p.V158Gfs*11 | Frame Shift Ins (INS) | VAF 21/76 reads (28%) | called by mutect2, pindel, varscan2
- NUP133 | c.952del p.E318Kfs*28 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- SETDB1 | c.673+2_673+6delinsC p.X225_splice | Splice Site (DEL) | VAF 38/109 reads (35%) | called by pindel, varscan2*
- ZNF285 | c.343del p.S115Lfs*11 | Frame Shift Del (DEL) | VAF 42/131 reads (32%) | called by mutect2, pindel, varscan2
- DIO2 | c.615G>A p.P205= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV70445289; called by muse, mutect2, varscan2
- DSEL | c.2313T>C p.H771= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV100025409; called by muse, mutect2, varscan2
- GRIN2A | c.936C>T p.Y312= | Silent (SNP) | VAF 75/137 reads (55%) | catalogued as rs765894828, COSV100409035; called by muse, mutect2, varscan2
- KARS1 | c.1611G>A p.L537= | Silent (SNP) | VAF 66/120 reads (55%) | catalogued as COSV100093897; called by muse, mutect2, varscan2
- LMTK3 | c.3381C>T p.P1127= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV99540169; called by muse, mutect2, varscan2
- NAA30 | c.318G>C p.L106= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV100035807; called by muse, mutect2, varscan2
- PEAR1 | c.1230C>T p.C410= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99440961; called by muse, mutect2
- PREPL | c.2013A>G p.T671= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV99576042; called by muse, mutect2, varscan2
- PTK2 | c.2968T>C p.L990= | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as COSV100569829; called by muse, mutect2, varscan2
- SAP18 | c.99C>T p.F33= (on ENST00000607003; = p.F52= on NM_005870.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs1565985552, COSV101229418; called by muse, mutect2, varscan2
- SSTR5 | c.840C>T p.P280= | Silent (SNP) | VAF 42/89 reads (47%) | catalogued as rs779150263, COSV99559596; called by muse, mutect2, varscan2
- SYNJ2 | c.2940G>A p.R980= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV100840097; called by muse, mutect2, varscan2
- PRR34 | n.325C>T | RNA (SNP) | VAF 21/49 reads (43%) | catalogued as rs776304261, COSV100412823; called by muse, mutect2, varscan2
